Somatic mutation profile of tumor specimen TARGET-10-PARPHB-09A (aliquot TARGET-10-PARPHB-09A-01D) from TARGET case TARGET-10-PARPHB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.1 years (400 days).
Specimen TARGET-10-PARPHB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2078bd51-ebc6-4a6d-9157-85ee7e309724.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARPHB-10A (Blood Derived Normal), aliquot TARGET-10-PARPHB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9299d4e-9948-40de-91aa-67c825502156

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT2 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs374357224, COSV99183692; called by muse, mutect2
- C1QTNF2 | c.311G>A p.R104Q (on ENST00000393975; = p.R59Q on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs759937511, COSV67432358; called by muse, mutect2, varscan2
- CATSPERE | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 117/282 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.033); catalogued as COSV63675686; called by muse, mutect2, varscan2
- DNAH5 | c.7916G>A p.R2639Q | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs140968268, COSV54202500; called by muse, mutect2
- NALCN | c.2898G>T p.L966F | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV51916108; called by muse, mutect2
- LCK | c.481+1del | Frame Shift Del (DEL) | VAF 10/14 reads (71%) | called by mutect2, varscan2
- ZNF682 | c.888G>A p.R296= | Silent (SNP) | VAF 25/231 reads (11%) | catalogued as rs1295889281; called by muse, mutect2, varscan2
